Somatic mutation profile of tumor specimen TARGET-10-PAPCVR-09A (aliquot TARGET-10-PAPCVR-09A-01D) from TARGET case TARGET-10-PAPCVR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,029 days).
Specimen TARGET-10-PAPCVR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4949cf8-5138-45b8-b18d-2c498a9115b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPCVR-10A (Blood Derived Normal), aliquot TARGET-10-PAPCVR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f66947c-9b38-4f87-a4f1-e2d523a0a38a

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HMGCS1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57289812; called by muse, mutect2, varscan2
- MTA2 | c.317G>A p.C106Y | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53873436; called by muse, mutect2, varscan2
- NLRP12 | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1268047610, COSV60745387, COSV60756025; called by muse, mutect2, varscan2
- RASA3 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373938545, COSV61866679; called by muse, mutect2, varscan2
- AMPH | c.1513del p.V505* | Frame Shift Del (DEL) | VAF 29/115 reads (25%) | called by mutect2, pindel, varscan2
- CCAR2 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CLCN6 | c.2586G>A p.L862= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as COSV56743673; called by muse, mutect2, varscan2
- IL17RB | c.627T>C p.A209= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- MPHOSPH10 | c.1665+125C>T | Intron (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
